Somatic mutation profile of tumor specimen MMRF_2019_1_BM_CD138pos (aliquot MMRF_2019_1_BM_CD138pos_T1_KHS5U_L08654) from MMRF case MMRF_2019, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.7 years (25,449 days).
Specimen MMRF_2019_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0abce5a9-f98a-4fb1-90e5-aa926c3601b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2019_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2019_1_PB_Whole_C2_KHS5U_L08655; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dfd1ef3-bc0a-4322-a2d4-9378e7b41cde

The open-access MAF lists 75 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 20, Silent 10, Intron 8, 5'UTR 5, 5'Flank 2, 3'Flank 1, Frame Shift Del 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBY2 | c.1267C>T p.R423C | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371167603, COSV60119561; called by muse, mutect2, varscan2
- CD151 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs775765246; called by muse, mutect2, varscan2
- CD44 | c.2050A>G p.I684V | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1444025576; called by muse, mutect2, varscan2
- CLEC14A | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as rs760765387; called by muse, mutect2, varscan2
- DMKN | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs373879312; called by muse, mutect2, varscan2
- FLG2 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 206/339 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); catalogued as COSV66166982; called by muse, mutect2, varscan2
- MAP4 | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs754738213, COSV53142223; called by muse, mutect2, varscan2
- RESF1 | c.1520C>A p.P507H | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1216869962; called by muse, mutect2, varscan2
- TAL2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1259620152; called by muse, mutect2, varscan2
- TAS2R10 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs754929198, COSV99555664; called by muse, mutect2, varscan2
- TDRD7 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs199787418; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TXNRD1 | c.346G>A p.A116T (on ENST00000525566 / NM_001093771.3; = p.A18T on NM_003330.4) | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as rs778413832, COSV100723610, COSV61597908; called by muse, mutect2, varscan2
- ZNF776 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774740912, COSV57814343; called by muse, mutect2, varscan2
- ZNF835 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs915967063, COSV73379200; called by muse, mutect2, varscan2
- AKAP13 | c.2189A>T p.D730V | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2
- FAM168A | c.667C>A p.P223T (on ENST00000064778 / NM_001286050.2; = p.P214T on NM_015159.3) | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2
- GATA5 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRID1 | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- HID1 | c.1241-8T>G | Splice Region (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- IL18RAP | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.082); called by muse, mutect2
- IPO11 | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MEGF11 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- PARD3 | c.994del p.L332Ffs*63 | Frame Shift Del (DEL) | VAF 40/110 reads (36%) | called by mutect2, pindel, varscan2
- PTGES3L-AARSD1 | c.1525G>A p.A509T (on ENST00000421990 / NM_001136042.2; = p.A491T on NM_025267.3) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- PTPN1 | c.782T>A p.I261N | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RXRB | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMC1 | c.1687T>G p.Y563D | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TOM1L2 | c.949G>A p.A317T (on ENST00000379504 / NM_001350333.2; = p.A267T on NM_001033551.3) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.009); called by muse, mutect2
- VDR | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- AK7 | c.510G>A p.E170= | Silent (SNP) | VAF 10/12 reads (83%) | called by muse, varscan2
- C1orf105 | c.360C>T p.P120= | Silent (SNP) | VAF 84/325 reads (26%) | catalogued as COSV62959332; called by muse, mutect2, varscan2
- EFCAB8 | c.2163T>C p.S721= | Silent (SNP) | VAF 68/162 reads (42%) | catalogued as rs1182760434; called by muse, mutect2, varscan2
- F5 | c.1668C>T p.S556= | Silent (SNP) | VAF 12/235 reads (5%) | called by muse, mutect2
- FAM168A | c.669T>C p.P223= (on ENST00000064778 / NM_001286050.2; = p.P214= on NM_015159.3) | Silent (SNP) | VAF 65/146 reads (45%) | catalogued as COSV50356704; called by muse, mutect2
- FER1L5 | c.2526A>T p.I842= (on ENST00000623019; = p.I847= on NM_001293083.2) | Silent (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.246A>C p.T82= | Silent (SNP) | VAF 42/57 reads (74%) | catalogued as rs367734033; called by muse, varscan2
- PRIM2 | c.573T>A p.A191= | Silent (SNP) | VAF 114/240 reads (48%) | called by muse, mutect2, varscan2
- SLC38A1 | c.423C>T p.V141= | Silent (SNP) | VAF 82/201 reads (41%) | called by muse, mutect2, varscan2
- WDFY4 | c.7218A>G p.E2406= | Silent (SNP) | VAF 19/159 reads (12%) | called by muse, mutect2, varscan2
- AC004947.2 | chr7:26534159 C>T | 5'Flank (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- ASB1 | c.*4189C>T | 3'UTR (SNP) | VAF 54/118 reads (46%) | catalogued as rs1191570301; called by muse, mutect2, varscan2
- B3GALT5 | c.*199A>C | 3'UTR (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021462 G>C | 5'Flank (SNP) | VAF 30/70 reads (43%) | catalogued as COSV55847618, COSV55848399; called by muse, mutect2, varscan2
- CYP3A5 | c.318+1313C>T | Intron (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2, varscan2
- DENND1B | c.*1321C>T | 3'UTR (SNP) | VAF 77/119 reads (65%) | called by muse, mutect2, varscan2
- DIPK1B | chr9:136726077 C>T | 3'Flank (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- DUSP2 | c.510+154G>C | Intron (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2, varscan2
- EARS2 | c.139+23T>G | Intron (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- EID1 | c.*492C>T | 3'UTR (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
- ERC1 | c.-62G>T | 5'UTR (SNP) | VAF 100/225 reads (44%) | called by muse, mutect2, varscan2
- FAM234B | c.*330A>T | 3'UTR (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- FUT3 | c.*112T>A | 3'UTR (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- FUT4 | c.*1711A>G | 3'UTR (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- IFT172 | c.336+16G>C | Intron (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- IGLL5 | c.-96C>A | 5'UTR (SNP) | VAF 35/40 reads (88%) | catalogued as COSV73250060, COSV73250979; called by muse, mutect2, varscan2
- LILRB5 | c.1357+111C>G | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- LIMK2 | c.*468C>G | 3'UTR (SNP) | VAF 51/124 reads (41%) | called by muse, mutect2, varscan2
- LNPK | c.*1503G>C | 3'UTR (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- LONRF2 | c.*4279G>A | 3'UTR (SNP) | VAF 26/73 reads (36%) | catalogued as rs1205106220; called by muse, mutect2
- LRRC49 | c.*99A>G | 3'UTR (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- MAFF | c.*1568T>C | 3'UTR (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- MMRN2 | c.*989T>A | 3'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- MYO1E | c.-95del | 5'UTR (DEL) | VAF 25/70 reads (36%) | catalogued as rs1484292271, COSV55682981; called by mutect2, pindel, varscan2
- PIGW | c.*634T>C | 3'UTR (SNP) | VAF 9/18 reads (50%) | catalogued as rs932043143; called by muse, mutect2
- PLCB1 | c.1888+82G>C | Intron (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2
- PTGES3 | c.-18C>A | 5'UTR (SNP) | VAF 20/48 reads (42%) | catalogued as rs189988970; called by muse, mutect2, varscan2
- SCAND1 | c.-71C>T | 5'UTR (SNP) | VAF 74/176 reads (42%) | called by muse, mutect2, varscan2
- SLAMF1 | c.415+75A>T | Intron (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- TECRL | c.*227del | 3'UTR (DEL) | VAF 44/129 reads (34%) | called by mutect2, pindel, varscan2
- TRIM44 | c.*1043_*1050del | 3'UTR (DEL) | VAF 18/208 reads (9%) | called by mutect2, pindel
- TTC32 | c.*338A>C | 3'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, varscan2
- TTN | c.*885A>G | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- TUBGCP2 | c.*19A>C | 3'UTR (SNP) | VAF 200/512 reads (39%) | called by muse, mutect2, varscan2
- VMP1 | c.1077+159T>C | Intron (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- WWTR1 | c.*2413T>A | 3'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
